Somatic mutation profile of tumor specimen TCGA-49-AAR3-01A (aliquot TCGA-49-AAR3-01A-11D-A410-08) from TCGA case TCGA-49-AAR3, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.7 years (25,469 days).
Specimen TCGA-49-AAR3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d21dcbc-0fcc-4694-aa8a-52f3a51a2ccb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-AAR3-11A (Solid Tissue Normal), aliquot TCGA-49-AAR3-11A-11D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9771081f-8e15-4df0-b25c-1c03c4a89ba6

The open-access MAF lists 126 somatic variants for this specimen: 96 protein-altering or splice-affecting, 23 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 23, Splice Site 3, Nonsense Mutation 3, 5'Flank 3, Intron 2, Frame Shift Del 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMUT | c.1880A>G p.H627R | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs372486357, CM002070; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACADM | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100273498; called by muse, mutect2
- ACSM2A | c.1456C>A p.P486T (on ENST00000219054; = p.P407T on NM_001308169.2) | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99525545; called by muse, mutect2
- ADCK2 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99301805; called by muse, mutect2, varscan2
- AGTR1 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV100837128; called by muse, mutect2, varscan2
- AHNAK | c.16577G>T p.G5526V | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99948917; called by muse, mutect2, varscan2
- ARID2 | c.4240A>T p.R1414* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100536739, COSV57604112; called by muse, mutect2, varscan2
- ARMT1 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.619); catalogued as rs1398633227, COSV100939835; called by muse, mutect2
- ASTN1 | c.1849T>A p.C617S | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99922689; called by muse, mutect2
- BTG4 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs992892482, COSV63635512; called by muse, mutect2, varscan2
- CADM3 | c.551A>G p.N184S (on ENST00000368125 / NM_001127173.3; = p.N218S on NM_021189.5) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.241); catalogued as rs770392248, COSV100930392; called by muse, mutect2, varscan2
- CAPRIN2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV99195593; called by mutect2, varscan2
- CCDC59 | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV99810768; called by muse, mutect2
- CDH9 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99151120; called by muse, mutect2
- CEP126 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as rs752991138, COSV99681336; called by muse, mutect2, varscan2
- CILP | c.3419C>A p.S1140Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV99973795; called by muse, mutect2, varscan2
- CMTR2 | c.14G>T p.R5I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV100579297; called by muse, mutect2
- CTC1 | c.1965G>C p.E655D | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV100236684; called by muse, mutect2
- CTNNA3 | c.35A>T p.D12V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs730880069, COSV100373728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DKK2 | c.293C>G p.S98W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53403075, COSV99569303; called by muse, mutect2, varscan2
- DSC3 | c.2543A>T p.Y848F | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1163586327, COSV100844686; called by muse, mutect2
- EMSY | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58260861; called by muse, mutect2
- ENTPD7 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV100978476; called by muse, mutect2
- FAT3 | c.13487C>A p.T4496K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.014); catalogued as COSV99969046; called by muse, mutect2
- FBXL7 | c.1360T>A p.F454I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV100310510, COSV61647932; called by muse, mutect2, varscan2
- FLG | c.2820G>T p.R940S | Missense Mutation (SNP) | VAF 25/381 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV100911948, COSV64243201; called by muse, mutect2
- FLRT1 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.893); catalogued as COSV55361050; called by muse, mutect2
- FOXP2 | c.1376A>T p.Q459L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV100647179; called by muse, mutect2, varscan2
- FRMPD4 | c.3898A>T p.T1300S | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV101043730; called by muse, mutect2, varscan2
- GHSR | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99577128; called by muse, mutect2, varscan2
- GKN1 | c.132T>G p.N44K | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV100933603; called by muse, mutect2
- GRXCR1 | c.856A>G p.K286E | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.011); catalogued as rs1307931347, COSV101295733; called by muse, varscan2
- HYDIN | c.14904C>A p.H4968Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.315); catalogued as COSV101125171; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1349A>G p.D450G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100149386; called by muse, mutect2, varscan2
- KEAP1 | c.302C>G p.A101G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99408128; called by muse, mutect2, varscan2
- KHDRBS3 | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100878906, COSV63419187; called by muse, mutect2, varscan2
- KLHL20 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV52943871, COSV99268600; called by muse, mutect2
- LAIR1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100479782; called by muse, mutect2, varscan2
- MARS2 | c.1675G>T p.G559* | Nonsense Mutation (SNP) | VAF 18/196 reads (9%) | catalogued as COSV99986674; called by muse, mutect2
- MARS2 | c.1676G>T p.G559V | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99986677, COSV99986711; called by muse, mutect2
- MSR1 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100027765; called by muse, mutect2
- MUC17 | c.13366G>A p.D4456N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.246); catalogued as COSV100074595; called by muse, mutect2, varscan2
- NBEA | c.6932A>G p.Y2311C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100082933; called by muse, mutect2, varscan2
- NCAM1 | c.440C>A p.P147Q | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1555112724, COSV100378318; called by muse, mutect2, varscan2
- NEXMIF | c.1602G>T p.K534N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99281217, COSV99281509; called by muse, mutect2, varscan2
- NF1 | c.1908del p.S637Vfs*51 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | catalogued as CD147162; called by mutect2, pindel, varscan2
- NIN | c.981+2T>A p.X327_splice | Splice Site (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99814665; called by muse, mutect2
- NOC4L | c.380A>T p.Q127L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV100223166; called by muse, mutect2
- NOTCH2 | c.4018G>T p.A1340S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV56696621; called by muse, mutect2
- OR10W1 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1476967739, COSV101223769; called by muse, mutect2
- OR5AN1 | c.880A>G p.R294G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV100004437; called by muse, mutect2, varscan2
- PAK5 | c.976A>G p.M326V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs899248640, COSV100781583; called by muse, mutect2, varscan2
- PARP4 | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV67961518; called by muse, mutect2
- PCDH15 | c.2894A>T p.Y965F | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100225578; called by muse, mutect2
- PCDHA8 | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.309); catalogued as rs781885344, COSV100969169; called by muse, mutect2, varscan2
- PI4KB | c.1960G>A p.V654M (on ENST00000368873 / NM_001369623.1; = p.V666M on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV99650030; called by muse, mutect2, varscan2
- PIK3C3 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100011427; called by muse, mutect2
- PMFBP1 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1001761603, COSV99401346; called by muse, mutect2, varscan2
- POLD1 | c.753G>T p.E251D | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV101486910; called by muse, mutect2
- PRKCE | c.2040G>C p.K680N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100079053; called by muse, mutect2
- PRRC2B | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100622081, COSV61938338; called by muse, mutect2
- PTRHD1 | c.29G>C p.R10P | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs767838756, COSV99579213; called by muse, mutect2
- RASA1 | c.2641G>C p.V881L | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99170286; called by muse, mutect2
- RAX | c.1018G>T p.G340W | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99900308; called by muse, mutect2, varscan2
- RDH8 | c.112G>T p.G38C (on ENST00000651512; = p.G18C on NM_015725.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99319487; called by muse, mutect2, varscan2
- RNASE10 | c.454T>G p.C152G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100116196; called by muse, mutect2, varscan2
- ROBO3 | c.1261T>A p.Y421N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101185146; called by mutect2, varscan2
- RSBN1L | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs762959199, COSV58506405; called by muse, mutect2
- RSU1 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100590671; called by muse, mutect2, varscan2
- SARAF | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV56358067, COSV99822869; called by muse, mutect2, varscan2
- SBSPON | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99817670; called by muse, mutect2, varscan2
- SDR42E1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs531784688, COSV100200774; called by muse, mutect2, varscan2
- SIPA1L2 | c.1886C>G p.T629R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.384); catalogued as COSV53390854, COSV99479294; called by muse, mutect2, varscan2
- SLC1A3 | c.1416C>G p.D472E | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99468035; called by muse, mutect2
- SLC2A14 | c.1010T>A p.V337E | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100533955; called by muse, mutect2
- SOAT1 | c.1597-2A>T p.X533_splice | Splice Site (SNP) | VAF 15/196 reads (8%) | catalogued as COSV100859022; called by muse, mutect2
- SPAM1 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99773304; called by muse, mutect2, varscan2
- SYNE2 | c.5907G>C p.M1969I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100648271; called by muse, mutect2
- TENM4 | c.5042T>C p.L1681P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99577452; called by muse, mutect2
- TNK2 | c.2516G>T p.R839L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.385); catalogued as rs113120669, COSV57365180; called by muse, mutect2
- TNN | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99512654; called by muse, mutect2
- TOR1AIP2 | c.1174G>T p.V392L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100857494; called by muse, mutect2, varscan2
- TP53 | c.880del p.E294Sfs*51 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; called by mutect2, pindel, varscan2
- TRO | c.2531G>C p.G844A | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99437027; called by muse, mutect2
- TTLL7 | c.1178A>T p.K393I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99552870; called by muse, mutect2
- UBA2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs781352231, COSV99875278; called by muse, mutect2
- UNC45B | c.1246C>A p.L416M | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as rs868486503, COSV52102700; called by muse, mutect2, varscan2
- VPS16 | c.1301A>G p.Y434C | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.747); catalogued as COSV100988557; called by muse, mutect2
- ZFHX3 | c.10868G>T p.R3623L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99214123; called by muse, mutect2
- ZFHX3 | c.4027G>C p.D1343H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV99214127; called by muse, mutect2, varscan2
- ZFYVE26 | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100720665; called by muse, mutect2, varscan2
- ZIM3 | c.1010G>A p.C337Y | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99518448; called by muse, mutect2, varscan2
- ZNF668 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.704); catalogued as rs1218719029, COSV100336819; called by muse, mutect2, varscan2
- ZNF761 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV61888069; called by muse, mutect2
- CT45A3 | c.535A>T p.K179* | Nonsense Mutation (SNP) | VAF 22/576 reads (4%) | called by muse, mutect2
- KDM5C | c.781+1del p.X261_splice | Splice Site (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- ALDH1L1 | c.2175G>T p.R725= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs1559917355, COSV99857315; called by muse, mutect2, varscan2
- ATG16L1 | c.504C>T p.A168= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV100731367; called by muse, mutect2
- CTBS | c.831G>T p.R277= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99759858; called by muse, mutect2
- DDR1 | c.1479G>C p.P493= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100241922; called by muse, mutect2, varscan2
- FLG | c.5592C>T p.V1864= | Silent (SNP) | VAF 16/408 reads (4%) | called by muse, mutect2
- GPATCH3 | c.430C>A p.R144= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV100658881; called by muse, mutect2
- HOXA1 | c.132C>T p.A44= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV99761357; called by muse, mutect2, varscan2
- KDM3A | c.3393C>A p.V1131= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100460035, COSV100460798; called by muse, mutect2
- LRRC8C | c.171A>G p.K57= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100968356; called by muse, mutect2
- MYO18B | c.3228C>T p.T1076= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs1569098998, COSV100123126, COSV59130039; called by muse, mutect2, varscan2
- NFATC3 | c.1710A>G p.V570= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as rs981072067, COSV100285574; called by muse, mutect2
- NOTCH2 | c.4017G>T p.G1339= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99865993; called by muse, mutect2
- OR4K15 | c.60C>A p.S20= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100521068; called by muse, mutect2, varscan2
- OR6X1 | c.168A>T p.P56= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100020629; called by muse, mutect2, varscan2
- PCNX3 | c.5760G>A p.R1920= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100856569; called by muse, mutect2
- RBM15B | c.1005C>T p.A335= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100082282; called by muse, mutect2, varscan2
- RELN | c.6597T>C p.S2199= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV100634498; called by muse, mutect2, varscan2
- RNF217 | c.996C>T p.Y332= (on ENST00000521654 / NM_001286398.2; = p.Y40= on NM_152553.5) | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV51574873, COSV51577777; called by muse, mutect2
- SIGLEC8 | c.903C>A p.T301= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV58476098; called by muse, mutect2
- SLC25A13 | c.1732C>T p.L578= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV99674011; called by muse, mutect2
- SPDYE3 | c.1462T>C p.L488= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV100193794; called by muse, mutect2, varscan2
- TEX47 | c.477C>T p.D159= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs369625195; called by muse, mutect2
- TOMM40L | c.888C>T p.R296= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs1046029232, COSV100915823; called by muse, mutect2, varscan2
- ADAD2 | c.419-281C>T | Intron (SNP) | VAF 3/17 reads (18%) | catalogued as rs753702534, COSV51893921; called by muse, mutect2
- AL353804.7 | chrX:73847112 C>A | 5'Flank (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847113 C>A | 5'Flank (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851624 A>T | 3'Flank (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- CD300LD | chr17:74592335 A>G | 5'Flank (SNP) | VAF 8/53 reads (15%) | catalogued as rs1015361591; called by muse, mutect2, varscan2
- HS3ST2 | c.*1G>A | 3'UTR (SNP) | VAF 7/98 reads (7%) | catalogued as COSV99758436; called by muse, mutect2
- WNK1 | c.2140-3150G>A | Intron (SNP) | VAF 6/116 reads (5%) | catalogued as COSV100268143; called by muse, mutect2
